Somatic mutation profile of tumor specimen TCGA-BR-4183-01A (aliquot TCGA-BR-4183-01A-02D-1126-08) from TCGA case TCGA-BR-4183, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 55.9 years (20,420 days).
Specimen TCGA-BR-4183-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6684a754-53af-40e6-bbbb-5865b1517f7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4183-11A (Solid Tissue Normal), aliquot TCGA-BR-4183-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87ce0cd7-9c18-4dbb-821e-ea474cd52c44

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 32, Silent 14, Nonsense Mutation 3, Frame Shift Del 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NAP1L3 | c.1505A>C p.K502T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV59073839, COSV59074072, COSV59075074; called by mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs756182664, COSV68066508; called by mutect2, varscan2
- ALLC | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs1168305633, COSV52993269; called by muse, mutect2, varscan2
- ARHGEF6 | c.1410C>A p.Y470* | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | catalogued as COSV51688126; called by muse, mutect2
- ATP6V0A4 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV59473199; called by mutect2, varscan2
- BRWD3 | c.1907G>A p.G636E | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.778); catalogued as COSV64744836; called by muse, mutect2
- CACNA1E | c.3919G>A p.A1307T | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs373085902; called by muse, mutect2, varscan2
- CACNG6 | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV53165909; called by muse, mutect2, varscan2
- CEP192 | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs780716624, COSV58060886; called by muse, mutect2, varscan2
- COL7A1 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs528257059, COSV60392173; called by muse, mutect2, varscan2
- FBN3 | c.3970G>T p.E1324* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV54454967; called by muse, mutect2, varscan2
- FRMD7 | c.1259A>G p.D420G | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV53744987; called by muse, mutect2, varscan2
- FRY | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV66566341; called by muse, mutect2, varscan2
- LAMB2 | c.4877G>A p.R1626Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs752674803, COSV59731108, COSV59731439; called by muse, mutect2, varscan2
- LAMP2 | c.963G>C p.W321C | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52351748; called by muse, mutect2, varscan2
- MAGEE2 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1449563243, COSV64897424; called by muse, mutect2, varscan2
- MISP | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs898863457, COSV53119108; called by muse, mutect2
- MUC6 | c.6387_6389del p.S2130del | In Frame Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs765184193; called by pindel, varscan2
- OR1E1 | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV59458542; called by muse, mutect2
- OR2T12 | c.929A>C p.K310T | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1349094764, COSV58776665; called by muse, mutect2, varscan2
- OR5R1 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56571664; called by muse, mutect2, varscan2
- PISD | c.731T>C p.V244A (on ENST00000439502 / NM_001326412.1; = p.V210A on NM_014338.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV56716296; called by muse, mutect2, varscan2
- PSG8 | c.1226T>A p.M409K | Missense Mutation (SNP) | VAF 79/363 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV60609937, COSV60612161; called by muse, mutect2, varscan2
- RANBP6 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52388434; called by muse, mutect2, varscan2
- RARB | c.1181G>C p.R394P (on ENST00000383772 / NM_001290216.2; = p.R387P on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV51969306, COSV51969692; called by muse, mutect2, varscan2
- SH3KBP1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.467); catalogued as rs1386870517, COSV65639683; called by muse, mutect2, varscan2
- SIX6 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1238665108, COSV59801701; called by muse, mutect2, varscan2
- SOX6 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as rs774770291, COSV57039221; called by muse, mutect2, varscan2
- SPTA1 | c.1029G>T p.E343D | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV63749911; called by muse, mutect2, varscan2
- SREBF2 | c.1280A>G p.N427S | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.606); catalogued as rs748435330, COSV63330592; called by muse, mutect2, varscan2
- TADA1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs367923603; called by muse, mutect2, varscan2
- TOGARAM2 | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs756772607, COSV65420229; called by muse, mutect2, varscan2
- TTN | c.81349A>G p.S27117G (on ENST00000591111; = p.S19693G on NM_003319.4) | Missense Mutation (SNP) | VAF 18/191 reads (9%) | PolyPhen benign (0.033); catalogued as COSV59919937; called by muse, mutect2
- UGGT1 | c.2907T>G p.F969L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV52132792, COSV52133026; called by muse, mutect2, varscan2
- ZNF43 | c.1024T>C p.Y342H | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61683012; called by muse, mutect2
- CUL9 | c.6328_6331del p.V2110* | Frame Shift Del (DEL) | VAF 29/139 reads (21%) | called by mutect2, pindel, varscan2
- AC244197.3 | c.525C>T p.S175= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as rs372340411, COSV100558021, COSV61711499; called by muse, mutect2
- ANO6 | c.1524G>A p.T508= | Silent (SNP) | VAF 20/194 reads (10%) | catalogued as rs752518869, COSV57657857; called by muse, mutect2, varscan2
- CA6 | c.615G>T p.L205= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as rs151137875; called by muse, mutect2, varscan2
- CADM1 | c.1029C>A p.T343= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1565299292, COSV59003576; called by muse, varscan2
- CIB2 | c.507C>T p.F169= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs768407461, COSV51947711, COSV51947724; called by mutect2, varscan2
- CRHR2 | c.990C>T p.P330= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as rs774059129, COSV59264119; called by muse, mutect2, varscan2
- ITIH1 | c.2466G>A p.R822= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV56252963; called by muse, mutect2, varscan2
- MXRA5 | c.6999C>T p.D2333= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as rs757304562, COSV54226607; called by muse, mutect2, varscan2
- MYH2 | c.4908C>T p.N1636= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as COSV55433047; called by muse, mutect2, varscan2
- OSBPL5 | c.1908G>A p.T636= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs200519835, COSV55139921; called by muse, mutect2, varscan2
- OTX2 | c.735T>G p.A245= (on ENST00000408990 / NM_172337.3; = p.A253= on NM_021728.4) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV59765502; called by muse, mutect2, varscan2
- PCDHB7 | c.1329C>T p.D443= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as COSV50755986; called by muse, mutect2, varscan2
- POLR1A | c.975G>A p.T325= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs368437581; called by muse, mutect2, varscan2
- UFD1 | c.531C>T p.D177= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV54250395; called by muse, mutect2, varscan2
